Somatic mutation profile of tumor specimen TARGET-40-NAAHBU-02A (aliquot TARGET-40-NAAHBU-02A-01D) from TARGET case TARGET-40-NAAHBU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.9 years (4,342 days).
Specimen TARGET-40-NAAHBU-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15f74edc-fde1-4f27-8baf-d707d45c3e41.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBU-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4614807a-86ab-426c-9eb4-1a78102e75e6

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC1 | c.4769C>T p.P1590L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748744660, COSV100595156; called by muse, mutect2
- ATRX | c.830T>A p.V277D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64880418; called by muse, mutect2, varscan2
- DCLK2 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99651559; called by muse, mutect2, varscan2
- DYRK3 | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1179175313; called by muse, mutect2, varscan2
- MED23 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); catalogued as rs1390246500; called by muse, mutect2, varscan2
- SIRPA | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs370724960, COSV100605433; called by muse, mutect2, varscan2
- SORCS1 | c.2542C>T p.L848F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as COSV53911413; called by muse, mutect2, varscan2
- TACC2 | c.6056C>T p.S2019F (on ENST00000334433; = p.S97F on NM_006997.4) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166796802; called by muse, mutect2, varscan2
- DNAH5 | c.13761T>A p.Y4587* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- DNAH5 | c.1340A>G p.H447R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM5 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GXYLT1 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by mutect2, varscan2
- ITGB4 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM3B | c.1895A>G p.E632G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- MED23 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRUNE2 | c.4599A>T p.R1533S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SRCAP | c.8339G>A p.G2780E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.49795G>T p.V16599F (on ENST00000591111; = p.V9175F on NM_003319.4) | Missense Mutation (SNP) | VAF 44/171 reads (26%) | PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ABCA13 | c.13686C>T p.S4562= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV68947041; called by muse, mutect2, varscan2
- CRTC2 | c.1929G>T p.V643= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- DOP1A | c.6511C>T p.L2171= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- PPP2R1B | c.357G>A p.K119= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs367950455; called by muse, mutect2, varscan2
- TACC2 | c.7200C>T p.I2400= (on ENST00000334433; = p.I478= on NM_006997.4) | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV53281653; called by muse, mutect2, varscan2
- TERT | c.1854G>A p.T618= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs746040728, COSV57239665; ClinVar: likely benign; called by muse, mutect2, varscan2
- XPC | c.156A>T p.S52= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
